Gene-level copy-number profile of tumor specimen TCGA-EY-A3L3-01A from TCGA case TCGA-EY-A3L3, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 82.5 years (30,138 days).
Specimen TCGA-EY-A3L3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.b4ea4572-1e5e-48fd-85e0-2895acd6cd99.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EY-A3L3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 825 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/255e022f-0917-4a00-8d0b-d232309af88c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,118; copy number 2: 14,431; copy number 3: 27,135; copy number 4: 12,111; copy number 5: 2,104; copy number 6: 1,615; copy number 7: 390; copy number 8: 380; copy number 9: 52; copy number 10: 156; copy number 11: 208; copy number 12: 29; copy number 15: 15; copy number 17: 39; copy number 19: 4; copy number 25: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EY-A3L3-01A-11D-A227-01): tumor purity 0.91, ploidy 3.17, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,282 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,019,656–148,288,951, 47 genes, copy number 10–17: AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15, CHD1L, LINC00624, AC242426.1, OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1, GJA8, GPR89B, PDZK1P1, AC239803.1, LINC02804, RNU1-129P, RNVU1-7, PDE4DIPP1, NBPF11, PFN1P4, ABHD17AP1, LINC02805, AC239809.3, RNA5SP57, AC239809.1, AC239809.2, RNVU1-22, LINC01731, AC245100.3.
- chr1:148,295,180–148,358,686, 7 genes, copy number 10: LINC02806, AC245100.1, AC245100.5, Y_RNA, MIR5087, RNVU1-21, AC245100.6.
- chr1:149,782,689–149,812,373, 1 gene, copy number 11 (within-gene range 4–11): H2BC18.
- chr1:149,813,225–152,042,774, 130 genes, copy number 9–11 (within-gene range 4–11) (broad region; genes not listed).
- chr1:166,566,178–178,921,841, 244 genes, copy number 7–11 (broad region; genes not listed).
- chr1:179,954,773–180,909,166, 14 genes, copy number 12 (within-gene range 6–12): CEP350, RPSAP16, AL590632.1, AL390718.1, QSOX1, LHX4, ACBD6, VDAC1P4, MIR3121, OVAAL, Y_RNA, XPR1, U6, LINC02816.
- chr2:158,456,952–161,985,282, 59 genes, copy number 10–12 (within-gene range 3–12): PKP4, RPL7AP22, PKP4-AS1, AC005042.1, AC005042.2, DAPL1, AC064843.1, OR7E89P, OR7E28P, OR7E90P, RNU2-21P, TANC1, BTF3L4P2, RNU6-580P, GSTM3P2, MIR6888, WDSUB1, BAZ2B, AC008277.1, AC008277.2, CAPZA1P2, Y_RNA, AC009506.1, AC009961.1, RPS3AP13, MARCHF7, CD302, LY75-CD302, AC009961.3, LY75, AC009961.2, PLA2R1, ITGB6, AC092153.1, LINC02478, RBMS1, MIR4785, AC096656.1, RN7SL423P, AC009313.1, TANK-AS1, TANK, AC009299.2, LINC01806, AC009299.1, PSMD14, MXRA7P1, RNA5SP108, TBR1, AC009487.1, AC009487.2, SLC4A10, AC009487.3, AHCTF1P1, AC092654.1, AC062022.1, AC062022.2, KRT18P46, RPEP5.
- chr7:130,206,344–134,350,791, 71 genes, copy number 10 (broad region; genes not listed).
- chr8:65,155,407–73,441,526, 134 genes, copy number 7–8 (broad region; genes not listed).
- chr8:73,511,276–73,511,654, 1 gene, copy number 7: AC018620.1.
- chr8:127,686,343–132,675,592, 55 genes, copy number 7 (within-gene range 3–7): CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1, ADCY8, AC103726.1, AC103726.2, AC087341.1, AC104257.1, SNORA72, AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6.
- chr10:71,212,570–81,137,335, 246 genes, copy number 8–25 (broad region; genes not listed).
- chr10:83,067,962–86,969,481, 55 genes, copy number 11–15 (within-gene range 3–15): RNU6-478P, MARK2P15, LINC02650, AC069540.2, AC069540.1, RNU6-129P, AL390786.1, RNU1-65P, HMGN2P8, AL603756.1, GHITM, CERNA2, C10orf99, CDHR1, LRIT2, RGR, LRIT1, LINC00858, CCSER2, RPL12P29, TNPO1P1, CACYBPP1, RPS3AP5, AL358787.2, LINC01519, AL358787.1, LINC02647, AC025428.1, LINC01520, AL731532.1, RNU6-325P, AL731532.2, GRID1-AS1, GRID1, AC022028.3, AC022028.2, RN7SKP238, AC022028.1, RNA5SP322, MIR346, AL844892.2, AL844892.1, WAPL, RNU6-780P, AL731569.1, RPL7AP8, OPN4, LDB3, AC067750.1, BMPR1A, RPAP2P1, RNU1-19P, MMRN2, AC025268.1, SNCG.
- chr10:121,133,090–121,598,458, 4 genes, copy number 7 (within-gene range 5–7): RPL19P16, LINC01153, RN7SKP167, FGFR2.
- chr11:15,605,484–16,758,340, 10 genes, copy number 10 (within-gene range 6–10): AC087379.2, AC087379.1, AC009869.1, LINC02682, SOX6, MIR6073, AC103794.1, AKR1B1P3, RN7SL188P, C11orf58.
- chr11:16,842,253–16,842,587, 1 gene, copy number 10: RN7SKP90.
- chr12:22,409,237–23,251,499, 13 genes, copy number 9 (within-gene range 3–9): AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2, AC087235.1.
- chr12:65,758,020–66,254,622, 14 genes, copy number 8 (within-gene range 3–8): RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3.
- chr16:16,760,905–19,173,578, 58 genes, copy number 7 (within-gene range 2–7): AC092326.1, AC098965.1, AC109446.3, TCERG1P2, AC109446.1, XYLT1, AC109446.2, AC099494.1, AC099494.2, AC099494.3, AC009152.6, AC009152.1, AC009152.3, AC109495.1, AC025277.1, RPL7P47, AC010601.1, AC010601.2, AC091489.1, AC091489.2, AC008785.1, AC126755.3, NPIPA8, AC126755.5, PKD1P4, MIR6511A4, AC126755.4, NPIPA9, PKD1P5, MIR6770-3, Y_RNA, AC126755.2, MIR3180-3, MIR3670-3, AC126755.1, MIR3179-3, NOMO2, MIR3670-4, MIR3179-4, AC136618.2, AC136618.1, ABCC6P1, RPS15A, AC138811.2, ARL6IP1, AC138811.1, SMG1, AC092287.1, TMC7, RNU6-1340P, AC099518.4, AC099518.2, COQ7, AC099518.1, AC099518.6, ITPRIPL2, AC099518.3, AC099518.5.
- chr16:19,555,240–20,797,581, 31 genes, copy number 7: VPS35L, AC002550.2, KNOP1, AC002550.1, IQCK, AC027130.1, LARP7P2, GPRC5B, GPR139, AC092132.2, AC092132.1, SNRPEP3, GP2, UMOD, PDILT, AC106796.1, ACSM5, AC137056.1, ACSM2A, AC137056.2, ACSM2B, AC141273.1, ACSM5P1, ACSM3, AC141273.3, AC141273.2, ACSM1, THUMPD1, AC004381.3, AC004381.4, AC004381.1.
- chr16:20,784,509–20,849,665, 3 genes, copy number 7 (within-gene range 4–7): RNU6-944P, REXO5, AC004381.2.
- chr16:70,802,084–71,230,722, 4 genes, copy number 7 (within-gene range 2–7): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.
- chr17:78,991,716–80,477,843, 42 genes, copy number 7: CANT1, C1QTNF1-AS1, C1QTNF1, ENGASE, RBFOX3, AC021534.1, AC233701.1, MIR4739, LINC02078, ENPP7, CBX2, CBX8, AC100791.2, LINC01977, CBX4, AC100791.1, LINC01979, LINC01978, TBC1D16, AC100791.3, AC116025.2, AC116025.1, CCDC40, MIR1268B, GAA, EIF4A3, AC087741.3, AC087741.2, CARD14, AC087741.1, SGSH, SLC26A11, RNF213, AC124319.1, AC124319.2, AC124319.3, RNF213-AS1, ENDOV, MIR4730, AC120024.1, AC120024.4, NPTX1.
- chr20:9,537,370–9,839,076, 1 gene, copy number 8 (within-gene range 5–8): PAK5.
- chr20:9,835,556–10,058,303, 3 genes, copy number 8: AL034427.1, PARAL1, ANKEF1.
- chr20:10,025,917–10,026,168, 1 gene, copy number 8: Metazoa_SRP.
- chr20:12,865,202–16,053,197, 33 genes, copy number 7 (within-gene range 5–7): LINC01722, AL078623.1, AL133331.1, LINC01723, SPTLC3, AL109983.1, ISM1, ISM1-AS1, AL050320.1, AL121782.1, TASP1, GAPDHP2, ESF1, NDUFAF5, SEL1L2, RNU6-278P, MACROD2, RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475, AL121584.1, ENSAP1.

Autosomal genes at a single copy (total copy number 1): 592. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
